Somatic mutation profile of tumor specimen TCGA-LN-A4A1-01A (aliquot TCGA-LN-A4A1-01A-21D-A27G-09) from TCGA case TCGA-LN-A4A1, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 60.1 years (21,954 days).
Specimen TCGA-LN-A4A1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c3a6499-8282-4022-91d2-cd2ee2907539.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A4A1-10A (Blood Derived Normal), aliquot TCGA-LN-A4A1-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1f6ddea3-2821-4f40-8ee9-6a53094ab355

The open-access MAF lists 126 somatic variants for this specimen: 98 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 26, Nonsense Mutation 5, Frame Shift Del 3, Splice Region 2, Frame Shift Ins 2, In Frame Del 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 191/339 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AXIN1 | c.170C>G p.S57W | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51987153; called by muse, mutect2, varscan2
- CA10 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); catalogued as rs766628041, COSV53342713; called by muse, mutect2, varscan2
- CAST | c.1672C>T p.R558C (on ENST00000341926; = p.R641C on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs1224971830, COSV99701339; called by muse, mutect2, varscan2
- CCDC88C | c.1045A>G p.M349V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.88); PolyPhen benign (0.086); catalogued as rs572844946; called by muse, mutect2, varscan2
- CELF1 | c.1106A>G p.Y369C (on ENST00000358597 / NM_001376422.1; = p.Y365C on NM_006560.4 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60111817; called by muse, mutect2, varscan2
- CRYBB1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs144372140; called by muse, mutect2, varscan2
- CSF2RA | c.633C>G p.D211E | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as COSV62626598; called by muse, mutect2, varscan2
- DDX4 | c.1943C>T p.S648L | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as rs1441008911, COSV61755475; called by muse, mutect2, varscan2
- EHD1 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs145274478; called by muse, mutect2, varscan2
- ERMARD | c.53A>G p.Y18C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs758842196; called by muse, mutect2, varscan2
- FITM1 | c.304T>C p.F102L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0.018); catalogued as COSV52825787; called by muse, mutect2, varscan2
- GARS1 | c.1402G>T p.D468Y | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66828085; called by muse, mutect2, varscan2
- GOLGA6B | c.1837C>T p.L613F | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.397); catalogued as rs1250859017; called by mutect2, varscan2
- INTS4 | c.409A>G p.I137V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.182); catalogued as rs1410122615; called by muse, mutect2, varscan2
- ITGA8 | c.2923G>T p.E975* | Nonsense Mutation (SNP) | VAF 13/28 reads (46%) | catalogued as COSV100959636; called by muse, mutect2, varscan2
- KCNQ4 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1181851856; called by muse, mutect2, varscan2
- KDM4C | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774702584; called by muse, mutect2, varscan2
- KIAA1109 | c.12061A>G p.M4021V | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1487760264; called by muse, mutect2, varscan2
- KIF13A | c.3646A>G p.I1216V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1218892982; called by muse, mutect2, varscan2
- KLHL20 | c.1648G>T p.A550S | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.824); catalogued as COSV52943169, COSV99268609; called by muse, mutect2, varscan2
- LRAT | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs1231354939, COSV100312134, COSV60476467; called by muse, mutect2, varscan2
- LRRC37A3 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as rs763629368; called by muse, mutect2, varscan2
- MTARC2 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); catalogued as rs1558068053; called by muse, mutect2, varscan2
- NOTCH1 | c.2297G>C p.G766A | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs374434131, COSV53063594; called by muse, varscan2
- NRXN3 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.049); catalogued as rs201052888; called by muse, mutect2, varscan2
- OR4K5 | c.679C>T p.L227F | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV100262294; called by muse, mutect2, varscan2
- P2RX4 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs754311085; called by muse, varscan2
- PCDHA1 | c.2246C>A p.S749* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV65373038; called by muse, mutect2, varscan2
- PCLO | c.9646T>G p.L3216V | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs750254988, COSV100439759; called by muse, mutect2, varscan2
- PLEKHH1 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.895); catalogued as rs573848643; called by muse, mutect2, varscan2
- REG3G | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as COSV99709703; called by muse, mutect2, varscan2
- REL | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs772899527, COSV54364800; called by muse, mutect2, varscan2
- SAP130 | c.2230A>G p.I744V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.025); catalogued as rs1435874452; called by muse, mutect2, varscan2
- SART3 | c.1912C>T p.P638S (on ENST00000228284; = p.P620S on NM_014706.4) | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.84); PolyPhen benign (0.015); catalogued as COSV57210367; called by muse, mutect2, varscan2
- SATL1 | c.65G>A p.S22N (on ENST00000395409; = p.S209N on NM_001012980.2) | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs190908833; called by muse, mutect2, varscan2
- SCYL1 | c.589G>T p.V197F | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV54214550; called by muse, mutect2, varscan2
- SEMA3D | c.979G>C p.D327H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99406589; called by muse, mutect2, varscan2
- SPATS2L | c.195G>T p.K65N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777020983; called by muse, mutect2, varscan2
- ZC3H18 | c.2128G>A p.V710I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.991); catalogued as rs370561351; called by muse, mutect2, varscan2
- ZNF485 | c.530A>G p.H177R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs372395438; called by muse, mutect2, varscan2
- ABCA9 | c.2547A>G p.I849M | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ADCYAP1R1 | c.312C>G p.N104K | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRV1 | c.3592G>A p.E1198K | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2
- AOC3 | c.1546C>G p.L516V | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ASB15 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- BCHE | c.41T>A p.F14Y | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- BICRAL | c.2200C>T p.L734F | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- C17orf58 | c.50dup p.M17Ifs*11 | Frame Shift Ins (INS) | VAF 39/73 reads (53%) | called by mutect2, pindel, varscan2
- CEMIP | c.3824del p.Q1275Rfs*14 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | called by mutect2, pindel, varscan2
- CLEC4G | c.754C>A p.Q252K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by mutect2, varscan2
- CLIC3 | c.36G>C p.A12= | Splice Region (SNP) | VAF 23/32 reads (72%) | called by muse, mutect2, varscan2
- CMYA5 | c.12025G>C p.V4009L | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CNTNAP5 | c.1572C>A p.D524E | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CR1L | c.1186G>T p.G396* | Nonsense Mutation (SNP) | VAF 67/156 reads (43%) | called by muse, mutect2, varscan2
- DNAH5 | c.13705A>T p.I4569F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- EHBP1 | c.263C>A p.P88H | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EHD1 | c.598T>C p.F200L | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- FLRT3 | c.1842A>G p.I614M | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HR | c.2706C>G p.S902R | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- HTR1D | c.729C>G p.H243Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KCNQ5 | c.2105T>C p.F702S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- KIF4A | c.1773A>T p.Q591H | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KMT2D | c.3900_3904del p.K1301Gfs*22 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | called by mutect2, pindel, varscan2
- KRT81 | c.1031C>G p.S344C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LIG4 | c.307G>T p.G103* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- MAML2 | c.2202dup p.P735Sfs*46 | Frame Shift Ins (INS) | VAF 24/57 reads (42%) | called by mutect2, pindel, varscan2
- MGAM | c.5093A>G p.K1698R | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NOTCH1 | c.2272_2273del p.E758Ifs*50 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | called by pindel, varscan2
- NPR2 | c.2638A>T p.M880L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR4K5 | c.678G>T p.W226C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- PAPOLG | c.1109A>G p.Y370C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDS5B | c.3535A>G p.M1179V | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PIK3CB | c.2491G>A p.G831S | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by mutect2, varscan2
- PLPP1 | c.184A>G p.I62V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP2CA | c.479A>G p.D160G | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PRDX2 | c.461A>T p.E154V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PROM2 | c.20T>A p.L7Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- RAVER1 | c.568A>C p.K190Q | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- RAVER2 | c.1145A>G p.N382S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- REG3G | c.177A>T p.K59N | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RGL2 | c.549C>G p.D183E | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (1); PolyPhen possibly damaging (0.848); called by muse, varscan2
- ROM1 | c.762T>A p.H254Q | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- RPN2 | c.353A>T p.E118V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RRBP1 | c.1897A>T p.K633* (on ENST00000377813 / NM_001365613.2; = p.K203* on NM_004587.3) | Nonsense Mutation (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.561C>A p.A187= (on ENST00000265814 / NM_001198628.1; = p.A160= on NM_004349.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- SALL1 | c.2169G>T p.M723I | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- SATL1 | c.66C>A p.S22R (on ENST00000395409; = p.S209R on NM_001012980.2) | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SEPHS1 | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC29A1 | c.767G>T p.G256V | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- SYNE3 | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- TASOR2 | c.5680C>G p.P1894A | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TFPT | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WAC | c.1363A>T p.I455L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ZNF165 | c.1152_1166del p.S384_T388del | In Frame Del (DEL) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- ZNF211 | c.1245C>A p.H415Q (on ENST00000347302 / NM_198855.4; = p.H428Q on NM_006385.5) | Missense Mutation (SNP) | VAF 17/25 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZNF592 | c.3439C>G p.Q1147E | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF696 | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ALS2 | c.2703A>G p.G901= | Silent (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- ATP8A1 | c.3189G>C p.L1063= | Silent (SNP) | VAF 15/20 reads (75%) | catalogued as rs913590426; called by muse, mutect2, varscan2
- BICRAL | c.2199G>T p.L733= | Silent (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
- CASP6 | c.6C>T p.S2= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs777518317; called by muse, mutect2, varscan2
- CASZ1 | c.1629C>T p.H543= | Silent (SNP) | VAF 14/41 reads (34%) | called by muse, mutect2, varscan2
- CDH4 | c.1515C>A p.P505= | Silent (SNP) | VAF 5/33 reads (15%) | called by mutect2, varscan2
- CHTOP | c.204A>G p.A68= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2
- EDC4 | c.606C>T p.F202= | Silent (SNP) | VAF 40/69 reads (58%) | catalogued as rs368076076, COSV99534366; called by muse, mutect2, varscan2
- ERVW-1 | c.324C>T p.Y108= | Silent (SNP) | VAF 15/46 reads (33%) | called by muse, mutect2, varscan2
- FAM83B | c.204C>G p.V68= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV60925684; called by muse, mutect2, varscan2
- HELZ2 | c.3240C>T p.D1080= (on ENST00000467148 / NM_001037335.2; = p.D511= on NM_033405.3) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs758579604, COSV64409483; called by muse, varscan2
- KCNB1 | c.915C>T p.L305= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV65567165; called by muse, mutect2, varscan2
- LRP2 | c.11340T>C p.H3780= | Silent (SNP) | VAF 30/44 reads (68%) | called by muse, mutect2, varscan2
- MYH7B | c.267G>A p.E89= | Silent (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- MYH9 | c.3801G>A p.V1267= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs1481520637; called by muse, mutect2, varscan2
- NR1H3 | c.396C>T p.Y132= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.6762C>T p.S2254= | Silent (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- PLG | c.1383T>G p.V461= | Silent (SNP) | VAF 8/40 reads (20%) | called by muse, mutect2, varscan2
- PNPLA6 | c.3378C>T p.P1126= (on ENST00000414982 / NM_001166111.2; = p.P1078= on NM_006702.5) | Silent (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- ROS1 | c.6975T>A p.P2325= | Silent (SNP) | VAF 17/74 reads (23%) | called by muse, mutect2, varscan2
- SP1 | c.1779C>T p.P593= (on ENST00000327443 / NM_138473.3; = p.P586= on NM_003109.1) | Silent (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- TMPRSS11A | c.72T>C p.I24= | Silent (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2, varscan2
- TNRC6B | c.2055C>T p.A685= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs748158394; called by muse, varscan2
- TPP2 | c.1047A>G p.V349= | Silent (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- TRIM38 | c.1008C>G p.V336= | Silent (SNP) | VAF 26/81 reads (32%) | called by muse, mutect2, varscan2
- VSIG4 | c.33G>A p.G11= | Silent (SNP) | VAF 26/32 reads (81%) | catalogued as COSV66075353; called by muse, mutect2, varscan2
- FAM183BP | n.1149C>A | RNA (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- HNF4A | c.1129+87T>C | Intron (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
